CCDI case PBBKIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/126eaab7-6bd2-4932-940f-7a1b37ed72d7

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,704 days).

Biospecimens (3 samples)
- Sample 0DAOBQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAOBR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAOBS: Tissue type: Normal; Specimen type: Solid Tissue.
